Somatic mutation profile of tumor specimen TCGA-UY-A9PF-01A (aliquot TCGA-UY-A9PF-01A-11D-A38G-08) from TCGA case TCGA-UY-A9PF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 77.9 years (28,470 days).
Specimen TCGA-UY-A9PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9531bd28-7627-473a-adf4-1f176a2de756.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A9PF-10A (Blood Derived Normal), aliquot TCGA-UY-A9PF-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77eff4e5-76ef-4da2-a699-a64282ca3b5d

The open-access MAF lists 532 somatic variants for this specimen: 372 protein-altering or splice-affecting, 140 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 321, Silent 140, Nonsense Mutation 29, Frame Shift Del 9, Intron 9, Splice Region 5, RNA 5, Splice Site 4, 5'UTR 3, 5'Flank 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.5515C>T p.Q1839* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as rs786204751, CM980143, COSV53732966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.6115G>A p.E2039K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs864622251, CM094668, COSV53740536, COSV53772321; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2, varscan2
- GFAP | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs58075601, CM023075, CM051059, COSV53653827; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3730C>T p.Q1244* (on ENST00000272895 / NM_173076.3; = p.Q926* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99791156; called by muse, mutect2, varscan2
- ACIN1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as COSV52982317; called by muse, mutect2, varscan2
- ACOT11 | c.1503G>A p.G501= | Splice Region (SNP) | VAF 23/178 reads (13%) | catalogued as COSV56366402; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ACTN1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV51997783, COSV99518172; called by muse, mutect2, varscan2
- ADAMTS3 | c.2251C>A p.H751N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV54403288; called by muse, mutect2, varscan2
- ADORA1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs199829860, COSV55144309; called by muse, mutect2
- AFAP1L2 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV58418725; called by muse, mutect2, varscan2
- AFF1 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.081); catalogued as COSV57124491; called by muse, mutect2, varscan2
- AGL | c.1188A>G p.A396= | Splice Region (SNP) | VAF 26/84 reads (31%) | catalogued as COSV54058932; called by muse, mutect2, varscan2
- AHNAK2 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as COSV100318395; called by muse, mutect2
- AK6 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV66459493; called by muse, mutect2, varscan2
- AKT1S1 | c.380-1G>A p.X127_splice (on ENST00000344175 / NM_001098633.4; = p.X147_splice on NM_032375.5) | Splice Site (SNP) | VAF 15/77 reads (19%) | catalogued as COSV59278171; called by muse, mutect2, varscan2
- ALB | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV55740289; called by muse, mutect2, varscan2
- ALMS1 | c.5287G>C p.E1763Q | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52522350; called by muse, mutect2, varscan2
- AMZ1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1288129639, COSV56689176; called by muse, mutect2, varscan2
- ANKRD6 | c.1883C>T p.P628L (on ENST00000339746 / NM_001242809.2; = p.P623L on NM_014942.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1237983071, COSV60237211; called by muse, mutect2, varscan2
- APBA2 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.041); catalogued as COSV68795563; called by muse, mutect2, varscan2
- AR | c.877T>G p.S293A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV65960269, COSV65964282; called by muse, mutect2, varscan2
- AREG | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV52645233; called by muse, mutect2, varscan2
- ARHGAP25 | c.68C>T p.S23L (on ENST00000409202 / NM_001007231.3; = p.S16L on NM_014882.3) | Missense Mutation (SNP) | VAF 127/266 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54909327; called by muse, mutect2, varscan2
- ARHGAP32 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.448); catalogued as COSV59855876; called by muse, varscan2
- ARHGDIA | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs759174824, COSV53907818; called by muse, varscan2
- ARHGEF17 | c.3456C>T p.F1152= | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55238309; called by muse, mutect2, varscan2
- ARID2 | c.1723_1742del p.F575Efs*7 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as COSV57614789; called by pindel, varscan2
- ARID2 | c.3298C>T p.Q1100* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV57601004, COSV57608342; called by muse, mutect2, varscan2
- ARL4C | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1452320016, COSV60214645; called by muse, mutect2, varscan2
- ASAP3 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60877532, COSV60878081; called by muse, mutect2, varscan2
- ASB8 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763931728, COSV56660474; called by muse, mutect2, varscan2
- ATG9B | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99871950; called by muse, mutect2, varscan2
- ATP10D | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV56713661, COSV99905937; called by muse, mutect2, varscan2
- B3GALT4 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs752684062, COSV65852152; called by muse, mutect2, varscan2
- BACH1 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV54521242; called by muse, mutect2, varscan2
- BICD2 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV63550978; called by muse, mutect2, varscan2
- BMF | c.483G>C p.W161C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55019610; called by muse, mutect2, varscan2
- BSPRY | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV65243550; called by muse, mutect2, varscan2
- BSX | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58006152, COSV58006349; called by muse, mutect2, varscan2
- C3orf70 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.281); catalogued as rs1251042921, COSV58590714; called by muse, mutect2, varscan2
- CABS1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56734583; called by muse, mutect2, varscan2
- CACNA1I | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.183); catalogued as rs1320353948, COSV60811856; called by muse, mutect2
- CACNG8 | c.392T>G p.F131C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54416780; called by muse, mutect2, varscan2
- CALCA | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59027461, COSV59028761; called by muse, mutect2, varscan2
- CAPS | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs991997334, COSV50386529; called by muse, mutect2, varscan2
- CAPZA1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV54147309; called by muse, mutect2, varscan2
- CARD11 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV62720114; called by muse, mutect2, varscan2
- CAV3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.61); catalogued as rs1353541488, COSV100664399; called by muse, mutect2
- CCDC51 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs201340866; called by muse, mutect2, varscan2
- CCDC90B | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1392122136, COSV52625189; called by muse, mutect2, varscan2
- CDH18 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56923785; called by muse, mutect2, varscan2
- CDH24 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752887104, COSV57463674; called by muse, mutect2, varscan2
- CDK3 | c.661_688del p.T221Sfs*111 | Frame Shift Del (DEL) | VAF 18/194 reads (9%) | catalogued as rs767680152; called by mutect2, pindel
- CELA1 | c.251A>C p.D84A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV53331834; called by muse, mutect2, varscan2
- CEP85L | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100874287; called by muse, mutect2, varscan2
- CFAP58 | c.1277A>T p.D426V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57213642; called by muse, mutect2, varscan2
- CHGA | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53664625; called by muse, mutect2, varscan2
- CLDN4 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs200176069, COSV52896949, COSV99936548; called by muse, mutect2, varscan2
- CLEC3B | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV56109600; called by muse, mutect2, varscan2
- CLOCK | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100011905; called by muse, mutect2, varscan2
- CNKSR3 | c.1160T>C p.F387S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV70481685; called by muse, mutect2, varscan2
- CNST | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542933774, COSV63624400; called by muse, mutect2, varscan2
- CNTNAP2 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs867787078, COSV62260220; called by muse, mutect2, varscan2
- COL22A1 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57361368; called by muse, mutect2, varscan2
- COL2A1 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776292672, COSV61534644; called by muse, varscan2
- CORO1A | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54632213; called by muse, mutect2, varscan2
- CP | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV52834153; called by muse, mutect2, varscan2
- CPEB4 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as rs1054403947, COSV54176287; called by muse, mutect2, varscan2
- CSMD2 | c.7346C>T p.S2449L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53964605; called by muse, mutect2, varscan2
- CSPG4 | c.3200G>A p.S1067N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV57901662; called by muse, mutect2, varscan2
- CTNNA2 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs1258444394, COSV100561543, COSV58151794; called by muse, mutect2, varscan2
- CUL9 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV52734925; called by muse, mutect2, varscan2
- CYHR1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs751568222, COSV56763012; called by muse, mutect2, varscan2
- CYP27B1 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs745571910, COSV56986652; called by muse, mutect2, varscan2
- DCAF13 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV52574603; called by muse, mutect2, varscan2
- DCXR | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV60956950; called by muse, mutect2, varscan2
- DDR2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761583917, COSV63374549; called by muse, mutect2, varscan2
- DDX39B | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100385435, COSV58214075; called by muse, mutect2, varscan2
- DDX4 | c.1724A>C p.E575A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV61757411; called by muse, mutect2, varscan2
- DENND5B | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100171885; called by muse, mutect2, varscan2
- DEPDC1B | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54013270; called by muse, mutect2, varscan2
- DHX30 | c.2711C>T p.S904F (on ENST00000445061 / NM_138615.3; = p.S865F on NM_014966.3) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53142746; called by muse, mutect2, varscan2
- DHX57 | c.3803C>T p.S1268L | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54891368; called by muse, mutect2, varscan2
- DLEC1 | c.4112C>T p.S1371L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100343045; called by muse, mutect2
- DLGAP1 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1340542610, COSV59836978; called by muse, mutect2, varscan2
- DLL4 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs763165309, COSV51072693, COSV99989657; called by muse, mutect2, varscan2
- DNAH11 | c.13364G>A p.C4455Y | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV60982078; called by muse, mutect2
- DNAH3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.031); catalogued as rs1300932530, COSV51786833; called by muse, mutect2, varscan2
- DNAH8 | c.12427G>C p.E4143Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV59481184; called by muse, mutect2, varscan2
- DNTTIP1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.663); catalogued as rs1233535242, COSV54786388; called by muse, mutect2, varscan2
- DOCK3 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1240003740, COSV56550250; called by muse, mutect2, varscan2
- DOCK8 | c.1306C>G p.R436G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV66636139; called by muse, mutect2, varscan2
- EGLN2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.358); catalogued as COSV58281129, COSV58281277; called by muse, mutect2, varscan2
- EHBP1L1 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV58575179; called by muse, mutect2, varscan2
- EHD2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV54410988; called by muse, mutect2, varscan2
- EIF3K | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV50264393, COSV50264610; called by muse, mutect2, varscan2
- EIF4B | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1350108229, COSV50408564; called by muse, mutect2, varscan2
- EIF4G1 | c.1472T>C p.I491T (on ENST00000346169 / NM_198241.3; = p.I295T on NM_004953.5) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV59993964; called by muse, mutect2, varscan2
- EIF5B | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as rs953282620, COSV56816806; called by muse, mutect2, varscan2
- ELOVL1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV60523089; called by muse, mutect2, varscan2
- ENAH | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52873101; called by muse, mutect2, varscan2
- EPHA5 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56636204; called by muse, mutect2, varscan2
- EPHB3 | c.1419G>T p.W473C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57809193; called by muse, mutect2, varscan2
- EPS8 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99843464; called by muse, mutect2, varscan2
- ERCC2 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55542973, COSV55544824; called by muse, varscan2
- ESRRG | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100753534; called by muse, mutect2, varscan2
- EXOC2 | c.1144C>G p.L382V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57871998; called by muse, mutect2, varscan2
- EXOSC1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV61749784; called by muse, varscan2
- EXOSC7 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99652104; called by muse, mutect2
- FAM104A | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1269699430, COSV52148807; called by muse, mutect2, varscan2
- FAM118B | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs759376541, COSV100796932, COSV64157693; called by muse, mutect2, varscan2
- FAM71D | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as COSV100315308; called by muse, mutect2, varscan2
- FAM83H | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV66354693; called by muse, mutect2, varscan2
- FANCI | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55534970; called by muse, mutect2
- FKBP5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV61883902; called by muse, mutect2, varscan2
- FLG | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1240146425, COSV100912035, COSV64249637; called by muse, mutect2, varscan2
- FPR3 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV59329080; called by muse, mutect2, varscan2
- FRMD6 | c.355A>C p.N119H (on ENST00000344768 / NM_001267046.2; = p.N111H on NM_152330.4) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV61090847; called by muse, mutect2, varscan2
- GALNT1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV52455010; called by muse, mutect2, varscan2
- GAS7 | c.242C>G p.P81R (on ENST00000432992 / NM_201433.2; = p.P21R on NM_201432.2) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV60443882; called by muse, mutect2
- GBP6 | c.841_852del p.L281_G284del | In Frame Del (DEL) | VAF 11/68 reads (16%) | catalogued as COSV65012640; called by mutect2, pindel, varscan2
- GCDH | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs964724051, CM1414990, COSV53368672; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- GCDH | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV53368682; called by muse, varscan2
- GCM1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV52523995; called by muse, mutect2, varscan2
- GFER | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1006300352, COSV50191912; called by mutect2, varscan2
- GGA2 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV59170573; called by muse, mutect2, varscan2
- GIT1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1449649255, COSV56612839; called by muse, mutect2, varscan2
- GPATCH3 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64652723; called by muse, mutect2, varscan2
- GPR137 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV100464400; called by muse, mutect2
- GPSM2 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs763208536, COSV51444725; called by muse, mutect2, varscan2
- GPT | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV52954876; called by muse, mutect2, varscan2
- GPX2 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV50825550, COSV99962235; called by muse, mutect2, varscan2
- GREM2 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV58957386; called by muse, mutect2, varscan2
- GRIA4 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV56920291; called by muse, mutect2, varscan2
- GRM1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51176350; called by muse, mutect2, varscan2
- H2AJ | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.945); catalogued as rs955503054, COSV63762503, COSV63762596; called by muse, mutect2, varscan2
- HAUS2 | c.330G>C p.R110S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53001265; called by muse, mutect2, varscan2
- HDAC1 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV65192252; called by muse, mutect2, varscan2
- HELZ | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV62381028; called by muse, mutect2, varscan2
- HES4 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59243107; called by muse, mutect2, varscan2
- HIGD2A | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51258011; called by muse, mutect2, varscan2
- HMX2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs967343921, COSV60593511; called by muse, mutect2, varscan2
- HOXB1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV53318699; called by muse, mutect2, varscan2
- HOXC12 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1193463660, COSV54535701; called by muse, mutect2, varscan2
- HSD11B2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as COSV52099933; called by muse, mutect2, varscan2
- HSPA6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV100554248; called by muse, mutect2, varscan2
- HTR1F | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60391293; called by muse, mutect2, varscan2
- HTR1F | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60391309; called by muse, mutect2, varscan2
- HTT | c.4675G>A p.D1559N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61864757; called by muse, mutect2, varscan2
- ICE2 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149006481; called by muse, mutect2, varscan2
- IGFL1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs1416897926, COSV71443594, COSV71443610; called by muse, mutect2, varscan2
- IL17RC | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99925160; called by muse, mutect2, varscan2
- INPP4A | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99304693; called by muse, mutect2, varscan2
- ITGB1BP2 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV52140395; called by muse, mutect2, varscan2
- ITGB2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs747801038, CM151554, COSV56608442, COSV56614121; called by muse, mutect2, varscan2
- ITM2C | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58400343; called by muse, mutect2, varscan2
- ITPKC | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV54577397; called by muse, mutect2, varscan2
- ITPR1 | c.6517A>G p.M2173V (on ENST00000354582; = p.M2118V on NM_002222.7) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1421801695, COSV100232450; called by muse, mutect2
- JMJD1C | c.4538C>T p.S1513L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV59517888; called by muse, mutect2, varscan2
- KATNAL2 | c.1085G>A p.R362K (on ENST00000356157 / NM_001353899.1; = p.R290K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55308876; called by muse, mutect2, varscan2
- KCNB2 | c.1603C>G p.L535V | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV73053070; called by muse, mutect2
- KCNB2 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.207); catalogued as COSV73050310; called by muse, mutect2
- KCNC4 | c.1819G>T p.G607C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs1447449289, COSV100873661; called by muse, mutect2
- KIAA0753 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV63817038; called by muse, mutect2, varscan2
- KIAA1614 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as rs1385677021, COSV62550704, COSV62551317; called by muse, mutect2, varscan2
- KLF6 | c.286T>C p.C96R | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV51496254; called by muse, mutect2, varscan2
- KLHL36 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as rs781470535, COSV50724222; called by muse, mutect2, varscan2
- KLHL9 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100757139; called by muse, mutect2, varscan2
- KMT2A | c.6377C>T p.P2126L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV63292624; called by muse, mutect2, varscan2
- KMT2C | c.9254C>T p.P3085L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1266516224, COSV51433370, COSV51503115; called by muse, mutect2, varscan2
- KMT2E | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57579958; called by muse, mutect2, varscan2
- KNL1 | c.6726G>C p.E2242D (on ENST00000346991 / NM_170589.5; = p.E2216D on NM_144508.5) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61160514; called by muse, mutect2, varscan2
- KPRP | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as rs373463742, COSV64221551; called by muse, mutect2, varscan2
- KRT18 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.26); catalogued as rs1467314647, COSV101184075, COSV66316601; called by muse, varscan2
- LAMA1 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 12/132 reads (9%) | catalogued as COSV101057124, COSV67541525; called by muse, mutect2
- LENG1 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55368593; called by muse, mutect2, varscan2
- LIAS | c.436C>T p.R146C (on ENST00000261434 / NM_001363700.2; = p.R249C on NM_006859.4) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54697355; called by muse, mutect2, varscan2
- LONP2 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53526327; called by muse, mutect2, varscan2
- LRBA | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1332523519, COSV63965204; called by muse, mutect2, varscan2
- LRIT1 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV64513580; called by muse, mutect2, varscan2
- MACF1 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 34/110 reads (31%) | catalogued as COSV58403080; called by muse, mutect2, varscan2
- MAK16 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV62453685; called by muse, mutect2, varscan2
- MAMDC4 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.721); catalogued as COSV58074220; called by muse, mutect2
- MAML2 | c.179G>C p.R60P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101594181, COSV73264815; called by muse, mutect2
- MAP3K13 | c.2772G>T p.K924N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV53997869; called by muse, mutect2
- MAP3K4 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100815059, COSV100815076; called by muse, mutect2
- MCM9 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV60165461; called by muse, mutect2, varscan2
- MCMDC2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58041159; called by muse, mutect2, varscan2
- MED12 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs769202858, COSV61329448, COSV61343870, COSV61349385; called by muse, mutect2
- MED12L | c.4624G>A p.D1542N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV56398063; called by muse, mutect2, varscan2
- MED13 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63228721; called by muse, mutect2, varscan2
- MEF2A | c.416C>G p.S139* (on ENST00000557942 / NM_001319206.2; = p.S141* on NM_005587.4 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/140 reads (26%) | catalogued as COSV100573873; called by muse, mutect2, varscan2
- MFAP2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs146781619; called by muse, mutect2, varscan2
- MINDY3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1252537734, COSV53224453; called by muse, mutect2, varscan2
- MKNK1 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV100361428; called by muse, mutect2, varscan2
- MMP1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs750031506, COSV59511868; called by mutect2, varscan2
- MOCS1 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99226463; called by muse, mutect2, varscan2
- MOCS3 | c.554C>G p.T185S | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV54865558, COSV54867915; called by muse, mutect2
- MS4A14 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as rs751008533, COSV55738119; called by mutect2, varscan2
- MS4A7 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.543); catalogued as COSV55730820; called by muse, mutect2, varscan2
- MTMR4 | c.3527C>T p.S1176F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs931595757, COSV60203902; called by muse, mutect2, varscan2
- MUC16 | c.42901G>A p.D14301N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.954); catalogued as COSV66696700; called by muse, mutect2, varscan2
- MYBPC1 | c.3046G>A p.D1016N (on ENST00000550270 / NM_206820.2; = p.D1023N on NM_002465.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs763681033, COSV62257328, COSV62257693; called by muse, mutect2, varscan2
- MYEF2 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51054061; called by muse, mutect2, varscan2
- MYO5A | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62562521; called by muse, mutect2, varscan2
- MYO9A | c.4762G>C p.D1588H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV61858053; called by muse, varscan2
- MYO9A | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV61847857, COSV61858063; called by muse, varscan2
- MYO9A | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs141019429; called by muse, varscan2
- NCMAP | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65557678; called by muse, mutect2, varscan2
- NCOA1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV56053418; called by muse, mutect2, varscan2
- NDUFS4 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as COSV57021940; called by muse, mutect2, varscan2
- NFE2L3 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs754295738, COSV50239856; called by muse, mutect2, varscan2
- NFX1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as COSV59313557; called by muse, mutect2, varscan2
- NIP7 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV99650851; called by muse, mutect2, varscan2
- NLE1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1166394347, COSV62604845, COSV62605217; called by muse, mutect2
- NOL8 | c.1991C>A p.S664Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.458); catalogued as COSV62638106; called by muse, mutect2, varscan2
- NOX5 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV52996303; called by muse, varscan2
- NRDC | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1457182759, COSV100703964, COSV61409086; called by muse, mutect2, varscan2
- NUDT3 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101466201, COSV101466203; called by muse, mutect2
- NUP214 | c.3857G>A p.G1286E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV63913212; called by muse, mutect2, varscan2
- OR13J1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV65070336; called by muse, mutect2, varscan2
- OR2T11 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs758303018, COSV58187321; called by muse, mutect2, varscan2
- OR2T12 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100527678; called by muse, mutect2, varscan2
- OR52I2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs747433430, COSV57044821; called by muse, mutect2, varscan2
- OXR1 | c.994G>A p.E332K (on ENST00000442977 / NM_001198532.1; = p.E331K on NM_018002.3) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56336628; called by muse, mutect2, varscan2
- PAQR6 | c.727G>A p.E243K (on ENST00000292291 / NM_001272108.2; = p.E137K on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52744939, COSV99430938; called by muse, mutect2, varscan2
- PBX3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); catalogued as rs1183498146, COSV60731043; called by muse, mutect2, varscan2
- PBX4 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV52064590; called by muse, mutect2, varscan2
- PBXIP1 | c.1928T>C p.F643S | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63777723; called by muse, mutect2
- PCBP1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV57851950; called by muse, mutect2, varscan2
- PCDH1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54619601; called by muse, mutect2, varscan2
- PCSK9 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as COSV56164953; called by muse, mutect2, varscan2
- PDE12 | c.829T>A p.C277S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60819443; called by muse, mutect2, varscan2
- PER2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748337300, COSV54527942; called by muse, mutect2, varscan2
- PHC3 | c.2356G>A p.E786K (on ENST00000494943 / NM_001308116.2; = p.E798K on NM_024947.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV71949408; called by muse, mutect2, varscan2
- PHF3 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV50342771; called by muse, mutect2, varscan2
- PHF6 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59706690; called by muse, mutect2, varscan2
- PHKG1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as COSV51918992; called by muse, mutect2, varscan2
- PHLDB1 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.909); catalogued as COSV61881939; called by muse, mutect2, varscan2
- PHLPP1 | c.2587C>G p.Q863E | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV53038824; called by muse, mutect2, varscan2
- PIP5K1C | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.173); catalogued as rs780859590, COSV58956034; called by muse, mutect2, varscan2
- PIP5K1C | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs750488396, COSV58951274; called by muse, mutect2, varscan2
- PITX2 | c.349G>A p.E117K (on ENST00000354925 / NM_001204397.1; = p.E124K on NM_000325.6) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740015, COSV60741296; called by muse, mutect2, varscan2
- PLCB1 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62068983; called by muse, mutect2, varscan2
- PLS3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as COSV56777199; called by muse, mutect2, varscan2
- PNLIP | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65042015; called by muse, mutect2, varscan2
- POMGNT1 | c.1466A>T p.E489V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | PolyPhen probably damaging (0.997); catalogued as COSV64340967; called by muse, mutect2
- PPCS | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1364205580, COSV65333748; called by muse, mutect2, varscan2
- PPP4R4 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100428859; called by muse, mutect2, varscan2
- PRKAA1 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs918424548, COSV57186457; called by muse, mutect2, varscan2
- PRKDC | c.7877C>T p.S2626L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV58051387; called by muse, mutect2, varscan2
- PSD2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs150692464; called by muse, mutect2, varscan2
- PSMA5 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54749779; called by muse, mutect2, varscan2
- PTCH1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59479302; called by muse, mutect2, varscan2
- PTCHD4 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1191910977, COSV59797468; called by muse, mutect2, varscan2
- PTH2R | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55920466; called by muse, mutect2, varscan2
- PTPN23 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs1205602528, COSV55545515; called by muse, mutect2, varscan2
- PXMP2 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs371506840, COSV58095404; called by muse, mutect2, varscan2
- RAB11FIP2 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.164); catalogued as COSV62926156; called by muse, mutect2, varscan2
- RABGGTB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV60639110; called by muse, mutect2, varscan2
- RAP2B | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.813); catalogued as COSV60257522; called by muse, mutect2, varscan2
- REEP5 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV54844814; called by muse, varscan2
- REEP5 | c.522G>A p.A174= | Splice Region (SNP) | VAF 8/42 reads (19%) | catalogued as rs553914342, COSV54841651; called by muse, varscan2
- RHBDD1 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs1213306366, COSV58131699; called by muse, mutect2, varscan2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, mutect2, varscan2
- RMDN3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs1397999690, COSV53025602; called by muse, mutect2, varscan2
- RNF149 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs1188695326, COSV54865533; called by muse, mutect2, varscan2
- RNF180 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs747398962, COSV56965191; called by muse, varscan2
- RNF180 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as rs1412268121, COSV56965206; called by muse, varscan2
- RNF31 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1358080362, COSV53761355; called by muse, mutect2, varscan2
- RPF1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV65724791; called by muse, mutect2, varscan2
- RPS6KA5 | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as rs748176348, COSV56225850; called by muse, mutect2, varscan2
- RTTN | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55352268; called by muse, mutect2, varscan2
- RUSC1 | c.2497C>T p.Q833* (on ENST00000368352 / NM_001105203.2; = p.Q364* on NM_014328.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | catalogued as COSV99430126; called by muse, mutect2, varscan2
- S100A6 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63297154; called by muse, mutect2, varscan2
- SAMD15 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1323172169, COSV53628062; called by muse, mutect2, varscan2
- SASH1 | c.3652C>A p.Q1218K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as COSV66566070; called by muse, mutect2, varscan2
- SCCPDH | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63619372; called by muse, mutect2, varscan2
- SCRIB | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs1424323432, COSV57585979, COSV57593321; called by muse, mutect2, varscan2
- SDHC | c.18G>A p.L6= | Splice Region (SNP) | VAF 8/29 reads (28%) | catalogued as COSV60669324; called by muse, mutect2, varscan2
- SEPTIN7 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63257018; called by muse, mutect2, varscan2
- SERPINB6 | c.790G>A p.E264K (on ENST00000612421 / NM_001271823.2; = p.E245K on NM_004568.6) | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM102964, COSV59566398; called by muse, mutect2, varscan2
- SETD2 | c.3650G>T p.W1217L | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV57446359, COSV57452239; called by muse, mutect2
- SETX | c.3496G>A p.E1166K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV56394888; called by muse, mutect2, varscan2
- SFRP2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs754658364, COSV56838599; called by muse, mutect2, varscan2
- SKIDA1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71611147; called by muse, mutect2, varscan2
- SLC13A5 | c.587del p.Q196Rfs*13 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as COSV53425228; called by mutect2, pindel, varscan2
- SLC14A2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs768232144, COSV54908667; called by muse, mutect2, varscan2
- SLC26A5 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59705988; called by muse, mutect2, varscan2
- SLC28A2 | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61665321; called by muse, mutect2, varscan2
- SLC45A3 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV65655538; called by muse, mutect2, varscan2
- SLC4A7 | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99840110; called by muse, mutect2
- SMC5 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV63195636; called by muse, mutect2, varscan2
- SMG5 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV62436097; called by muse, mutect2, varscan2
- SNCG | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as rs1206267629, COSV62317988; called by muse, mutect2
- SNW1 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55057059; called by muse, mutect2, varscan2
- SPAG17 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs752713821, COSV60468721; called by muse, mutect2, varscan2
- SPAG5 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.095); catalogued as rs375467524, COSV58803057; called by muse, mutect2, varscan2
- SPEN | c.3893C>T p.S1298F | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs985320818, COSV65363028, COSV65367541; called by muse, mutect2, varscan2
- SRA1 | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as COSV51858887; called by muse, varscan2
- SRA1 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs1177464219, COSV51858892; called by muse, mutect2, varscan2
- SRSF12 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV71683792; called by muse, varscan2
- STAC2 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV61066864; called by muse, mutect2, varscan2
- STK3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV69227234; called by muse, mutect2
- STRN3 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62581999; called by muse, mutect2, varscan2
- SUPT5H | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV63242235; called by muse, mutect2, varscan2
- SVIL | c.5396G>A p.G1799E (on ENST00000355867 / NM_021738.3; = p.G1373E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100881435; called by muse, mutect2
- TACC1 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV52528886; called by muse, mutect2, varscan2
- TACC2 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV57773467; called by muse, mutect2, varscan2
- TAF4B | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs750602977, COSV52310324; called by muse, mutect2, varscan2
- TAF6L | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.015); catalogued as COSV53671010; called by muse, varscan2
- TANC2 | c.5449G>A p.E1817K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV67337275; called by muse, mutect2, varscan2
- TAS1R2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV64747326; called by muse, mutect2, varscan2
- TBC1D1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54727509; called by muse, mutect2, varscan2
- TBP | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as rs774242068, COSV57834040; called by muse, mutect2, varscan2
- TCHH | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV64277840; called by muse, mutect2, varscan2
- TENT5A | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60789586; called by muse, mutect2, varscan2
- TEX14 | c.2609G>C p.R870T (on ENST00000240361 / NM_001201457.2; = p.R864T on NM_031272.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99542989; called by muse, mutect2, varscan2
- THOC2 | c.3680C>T p.T1227I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV55555856; called by muse, mutect2, varscan2
- THRAP3 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.951); catalogued as COSV63568209; called by muse, mutect2, varscan2
- TIA1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs1485829059, COSV57008514; called by muse, mutect2, varscan2
- TMCC3 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54157763; called by muse, mutect2, varscan2
- TMEM106C | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV56743593; called by muse, mutect2, varscan2
- TMEM19 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57000215; called by muse, mutect2, varscan2
- TPRG1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100800679, COSV61466673; called by muse, mutect2, varscan2
- TREX1 | c.367G>C p.A123P (on ENST00000625293 / NM_033629.6; = p.A113P on NM_007248.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56498061; called by muse, mutect2, varscan2
- TRIM17 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV52859644; called by muse, mutect2, varscan2
- TRPM3 | c.3738G>A p.M1246I (on ENST00000357533 / NM_001366142.2; = p.M1101I on NM_020952.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV62595395; called by muse, mutect2, varscan2
- TTC22 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV64882047; called by muse, mutect2, varscan2
- TTC23 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV50444482; called by muse, mutect2, varscan2
- TTC39C | c.895G>A p.E299K (on ENST00000317571 / NM_001135993.2; = p.E238K on NM_153211.4) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV58218567; called by muse, mutect2, varscan2
- TTLL13P | c.258-1G>A p.X86_splice | Splice Site (SNP) | VAF 55/201 reads (27%) | catalogued as COSV60040212; called by muse, mutect2
- TXK | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV51919776, COSV99972424; called by muse, mutect2, varscan2
- TXNIP | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 37/184 reads (20%) | catalogued as COSV100997316; called by muse, mutect2, varscan2
- U2AF2 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV50044887; called by muse, mutect2, varscan2
- UBAP2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1242629063, COSV62549146; called by muse, mutect2, varscan2
- UBE4B | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53543847; called by muse, mutect2, varscan2
- UQCR10 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as rs377432442, COSV57458710; called by muse, mutect2, varscan2
- USP11 | c.2278G>A p.E760K (on ENST00000218348; = p.E717K on NM_001371072.1) | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV54476022; called by muse, mutect2, varscan2
- VARS2 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV52561255; called by muse, mutect2, varscan2
- VLDLR | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66074041; called by muse, mutect2, varscan2
- VMO1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761508508, COSV54498040; called by muse, mutect2, varscan2
- VWF | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764566111, COSV54619552; called by muse, mutect2, varscan2
- WDFY3 | c.8666A>T p.E2889V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55713988; called by muse, mutect2, varscan2
- WWC3 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66507490; called by muse, mutect2
- YARS2 | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61402578; called by muse, mutect2, varscan2
- ZBTB7B | c.1036C>T p.Q346* (on ENST00000292176; = p.Q380* on NM_001252406.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99421380; called by muse, mutect2, varscan2
- ZC3H13 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1194881971, COSV54463258, COSV99668630; called by muse, mutect2
- ZFYVE26 | c.6953T>A p.F2318Y | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV61333620; called by muse, mutect2, varscan2
- ZMIZ2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54811084; called by muse, mutect2, varscan2
- ZNF280D | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs866653627, COSV50996372; called by muse, mutect2, varscan2
- ZNF318 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58937787; called by muse, mutect2, varscan2
- ZNF462 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52951218; called by muse, mutect2, varscan2
- ZNF507 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.086); catalogued as rs144208852, COSV100321797; called by muse, mutect2, varscan2
- ZNF836 | c.1943G>A p.S648N | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.227); catalogued as COSV59086811; called by muse, mutect2, varscan2
- ZNFX1 | c.3824C>T p.S1275F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs1056459882, COSV65602003; called by muse, mutect2, varscan2
- ANKRD20A1 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2B1 | c.2711G>C p.R904P | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- BRF2 | c.1200_1201insCTTTCATCT p.R400_D401insLSS | In Frame Ins (INS) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- CACNA1B | c.1457G>A p.W486* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CRNKL1 | c.2286del p.E763Kfs*12 | Frame Shift Del (DEL) | VAF 58/253 reads (23%) | called by mutect2, pindel, varscan2
- EXOSC10 | c.1535_1559del p.L512Qfs*17 | Frame Shift Del (DEL) | VAF 31/120 reads (26%) | called by mutect2, pindel, varscan2
- GPR89B | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- H4C11 | c.199_202dup p.R68Hfs*45 | Frame Shift Ins (INS) | VAF 11/73 reads (15%) | called by mutect2, pindel
- KDM6A | c.1687_1693del p.P563Sfs*28 | Frame Shift Del (DEL) | VAF 17/31 reads (55%) | called by mutect2, pindel, varscan2
- LARS1 | c.622_634del p.T208Lfs*12 (on ENST00000394434 / NM_020117.11; = p.T181Lfs*12 on NM_016460.3) | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- SLC6A16 | c.758_765del p.K253Rfs*94 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- SLC9A5 | c.2644_2645del p.A882Yfs*35 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- ZNF792 | c.34-27_50del p.X12_splice | Splice Site (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- ABCC3 | c.1842G>A p.Q614= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV53329468; called by muse, mutect2, varscan2
- ABCC5 | c.1905C>T p.L635= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV55596515; called by muse, mutect2, varscan2
- ABCG5 | c.741C>T p.L247= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs769339847, COSV53212972, COSV53213577; called by muse, varscan2
- ABT1 | c.480C>T p.L160= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs781836950, COSV51293050; called by muse, mutect2, varscan2
- ACTG1 | c.891G>A p.T297= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs1555666491, COSV59512123; called by muse, mutect2, varscan2
- ADGRG1 | c.2016G>T p.L672= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV59652732; called by muse, mutect2, varscan2
- ADNP2 | c.2475C>T p.F825= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV51542499; called by muse, mutect2, varscan2
- AKAP13 | c.3423G>A p.V1141= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV63470102; called by muse, mutect2, varscan2
- AP1G1 | c.378C>T p.L126= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs374144112, COSV55491992; called by muse, mutect2, varscan2
- ARID2 | c.1803G>A p.R601= | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as COSV57614798; called by muse, varscan2
- ARMC4 | c.117G>A p.E39= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV59474260; called by mutect2, varscan2
- C11orf53 | c.273G>A p.G91= | Silent (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- C12orf57 | c.33G>A p.L11= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs782168213, COSV57547320; called by muse, mutect2, varscan2
- C12orf57 | c.234C>T p.V78= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV57547558; called by muse, mutect2, varscan2
- C1orf109 | c.87G>A p.Q29= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV59240499; called by muse, mutect2, varscan2
- CAPN5 | c.561C>T p.L187= (on ENST00000456580; = p.L147= on NM_004055.5) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53691441; called by muse, mutect2, varscan2
- CCDC92 | c.810C>T p.S270= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs144711865; called by muse, mutect2, varscan2
- CCHCR1 | c.612G>T p.L204= | Silent (SNP) | VAF 41/213 reads (19%) | catalogued as COSV100885600, COSV66185111; called by muse, mutect2, varscan2
- CDC42BPG | c.4077C>T p.L1359= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs746288078, COSV61349309; called by muse, mutect2, varscan2
- CHERP | c.576G>C p.L192= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV52227832; called by muse, varscan2
- CLCN6 | c.1635C>T p.I545= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs770524319, COSV56743176; called by muse, mutect2, varscan2
- CMIP | c.1851C>A p.R617= (on ENST00000537098 / NM_198390.2; = p.R523= on NM_030629.3) | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV67700352; called by muse, mutect2, varscan2
- CNPPD1 | c.897G>A p.L299= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs966377315, COSV55408981; called by muse, mutect2, varscan2
- COG7 | c.951C>T p.F317= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV56153244; called by muse, mutect2, varscan2
- CSNK1E | c.696G>A p.K232= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV63292158; called by muse, mutect2, varscan2
- CTH | c.120C>T p.P40= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs766581925, COSV100697171, COSV61009856; called by muse, mutect2, varscan2
- CTNND2 | c.2979C>T p.I993= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV58929229; called by muse, mutect2, varscan2
- CXCL6 | c.255G>A p.K85= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV56903502; called by muse, mutect2, varscan2
- DLG5 | c.643A>C p.R215= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV64950040; called by muse, mutect2, varscan2
- DNAJC13 | c.6731G>A p.*2244= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99607760; called by muse, mutect2, varscan2
- DSP | c.7656C>T p.L2552= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV65792766; called by muse, mutect2, varscan2
- EEF2 | c.1434C>T p.F478= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV58580998; called by muse, mutect2, varscan2
- ELF4 | c.391C>T p.L131= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV57455184; called by muse, mutect2, varscan2
- ETV1 | c.1122T>C p.R374= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1397059086, COSV54151633; called by muse, mutect2, varscan2
- EVA1A | c.228G>A p.E76= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV52062618, COSV99285322; called by muse, mutect2, varscan2
- EVPL | c.348G>A p.E116= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV56915568, COSV56916250; called by muse, mutect2, varscan2
- FAAP100 | c.654C>T p.F218= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59887739; called by muse, mutect2, varscan2
- FABP6 | c.93G>A p.R31= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV67437749; called by muse, mutect2, varscan2
- FAM98A | c.345C>T p.L115= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV53211978; called by muse, mutect2
- FBXL14 | c.1191G>A p.E397= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1258304497, COSV59337631; called by muse, mutect2, varscan2
- FOSL2 | c.156C>T p.N52= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs112541505, COSV53103321; called by muse, mutect2, varscan2
- FRYL | c.1710C>T p.D570= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs375198805; called by muse, mutect2, varscan2
- GAB4 | c.1644G>A p.K548= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV68755249; called by muse, mutect2, varscan2
- GATAD2A | c.807C>T p.L269= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1453238116, COSV53076211; called by muse, mutect2, varscan2
- GATB | c.51C>T p.F17= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs757217781, COSV56129302, COSV56131138; called by muse, mutect2, varscan2
- GRIA1 | c.24C>T p.F8= | Silent (SNP) | VAF 94/316 reads (30%) | catalogued as COSV53625115; called by muse, mutect2, varscan2
- GRM6 | c.2073C>T p.F691= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs914142828, COSV51449700; called by muse, mutect2
- HEATR5B | c.1911G>A p.L637= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV51859229; called by muse, mutect2, varscan2
- HECTD4 | c.10056C>T p.F3352= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1439449871, COSV66397510; called by muse, mutect2, varscan2
- HLA-DMB | c.723G>T p.R241= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV66870965; called by muse, varscan2
- HMG20A | c.12G>A p.L4= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV60314308; called by muse, mutect2, varscan2
- HSPA1B | c.1704G>A p.K568= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV65128403; called by muse, mutect2, varscan2
- IFT140 | c.3396C>T p.F1132= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV63699348; called by muse, mutect2, varscan2
- IL36G | c.417C>T p.F139= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV52079352; called by muse, mutect2, varscan2
- IQCH | c.1347G>A p.R449= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100246321, COSV60060099; called by muse, mutect2
- IRAK3 | c.270C>T p.L90= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV54166065; called by muse, mutect2, varscan2
- JMY | c.1506G>A p.R502= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV68662099; called by muse, mutect2, varscan2
- KCNB2 | c.1809C>T p.I603= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV73051111; called by muse, mutect2, varscan2
- KCNG4 | c.1251A>T p.T417= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV57586010; called by muse, mutect2, varscan2
- KCNH6 | c.1707G>A p.L569= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1182652804, COSV100121174; called by muse, mutect2, varscan2
- KIF18B | c.2178C>T p.L726= (on ENST00000593135 / NM_001265577.2; = p.L738= on NM_001264573.2) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1433611580, COSV59276343; called by muse, mutect2, varscan2
- KLRC2 | c.48C>T p.D16= | Silent (SNP) | VAF 18/239 reads (8%) | catalogued as COSV67900660; called by muse, mutect2
- LPAR6 | c.948C>T p.F316= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- LRRC8E | c.405C>T p.F135= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV60719263; called by muse, mutect2, varscan2
- LTK | c.2541C>T p.L847= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV53029339; called by muse, mutect2, varscan2
- MECR | c.27G>A p.R9= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs777964223, COSV55285564; called by muse, mutect2
- MKRN1 | c.819G>A p.V273= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV55438556; called by muse, mutect2, varscan2
- MMP14 | c.768C>T p.I256= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV61289583; called by muse, mutect2, varscan2
- MPPE1 | c.1113C>T p.L371= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV52334169; called by muse, mutect2, varscan2
- MTR | c.2188C>T p.L730= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV63966369; called by muse, mutect2, varscan2
- MYBBP1A | c.1173C>T p.F391= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV54604598; called by muse, mutect2, varscan2
- MYOF | c.3909C>T p.L1303= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1389189584, COSV63710814; called by muse, mutect2, varscan2
- MYOZ3 | c.651C>T p.F217= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV51741086; called by muse, mutect2, varscan2
- N6AMT1 | c.195T>A p.S65= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV58135750, COSV58135895; called by muse, mutect2, varscan2
- NGF | c.714G>A p.V238= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs776092330, COSV65689007; called by muse, mutect2, varscan2
- NMT1 | c.1155C>T p.F385= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs768875089, COSV51959078; called by muse, mutect2, varscan2
- NOC2L | c.2227C>T p.L743= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs760506748, COSV100498115; called by muse, varscan2
- NOL6 | c.699G>A p.L233= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1167090312, COSV53045997; called by muse, mutect2, varscan2
- NTRK2 | c.921G>A p.V307= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs752280623, COSV52882996; called by muse, mutect2, varscan2
- NUP88 | c.511C>T p.L171= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV56708022, COSV99851590, COSV99851942; called by muse, mutect2, varscan2
- OLR1 | c.33G>A p.V11= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1247827991, COSV58872750; called by muse, mutect2, varscan2
- OR5I1 | c.156G>A p.R52= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56889183; called by muse, mutect2, varscan2
- OR8K5 | c.519C>T p.V173= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV57888628; called by muse, mutect2, varscan2
- PARP16 | c.147C>T p.R49= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1218347177, COSV56036654; called by muse, mutect2, varscan2
- PDE3A | c.639C>T p.L213= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV62983165; called by muse, mutect2, varscan2
- PGM1 | c.129C>T p.I43= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs751419918, COSV64304522; called by mutect2, varscan2
- PHYKPL | c.297C>G p.T99= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs760026776, COSV57426390; called by muse, mutect2, varscan2
- PIK3CG | c.324G>A p.E108= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV63253800; called by muse, mutect2, varscan2
- PITPNM3 | c.2754G>A p.R918= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1275198190, COSV51472188; called by mutect2, varscan2
- PLAAT2 | c.462G>A p.L154= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV55375628; called by muse, mutect2, varscan2
- PPM1L | c.147G>A p.V49= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1355962020, COSV72263105, COSV72263569; called by muse, mutect2, varscan2
- PRPF8 | c.1368G>A p.L456= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100518057, COSV59267907; called by muse, mutect2, varscan2
- PSMG3 | c.123G>A p.K41= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs573973124, COSV52920980; called by muse, mutect2, varscan2
- PTPDC1 | c.198G>A p.E66= (on ENST00000375360 / NM_177995.3; = p.E118= on NM_152422.4) | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs962625934, COSV56626536; called by muse, mutect2, varscan2
- PTPRJ | c.3873C>T p.L1291= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs540802430, COSV69254726; called by muse, mutect2, varscan2
- PTPRO | c.49C>T p.L17= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55523271; called by muse, mutect2
- PURG | c.393G>A p.L131= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV53295591, COSV53296220; called by muse, mutect2, varscan2
- RABEP2 | c.270G>A p.L90= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV62869458; called by muse, mutect2
- RARG | c.954C>T p.L318= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV58432486; called by muse, mutect2, varscan2
- RARG | c.789C>T p.L263= | Silent (SNP) | VAF 63/245 reads (26%) | catalogued as COSV58433665, COSV58434837; called by muse, mutect2, varscan2
- RBM15B | c.1959C>T p.L653= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100082253; called by muse, mutect2
- RBMS3 | c.114C>A p.P38= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV56169274; called by muse, mutect2, varscan2
- RHBDF2 | c.1332T>C p.G444= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV51686417; called by muse, mutect2, varscan2
- RIPK4 | c.66C>T p.F22= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1462300291, COSV60191291; called by muse, mutect2, varscan2
- RYK | c.333C>T p.F111= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV56064509; called by muse, mutect2, varscan2
- SBF2 | c.4149C>T p.F1383= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as COSV56311799; called by muse, mutect2, varscan2
- SEC61A1 | c.60G>A p.Q20= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54579120; called by muse, mutect2, varscan2
- SFI1 | c.1293G>A p.Q431= (on ENST00000400288 / NM_001007467.3; = p.Q400= on NM_014775.4) | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as rs1256203234, COSV66292944, COSV66293378; called by muse, mutect2, varscan2
- SGIP1 | c.1278C>T p.P426= | Silent (SNP) | VAF 54/165 reads (33%) | catalogued as rs771506497, COSV52766003, COSV52779097; called by muse, mutect2, varscan2
- SH2D7 | c.1287G>A p.E429= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV51950148; called by muse, mutect2, varscan2
- SKI | c.498C>T p.I166= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs768733290, COSV101049502, COSV66013340; called by muse, mutect2, varscan2
- SLC26A6 | c.795C>T p.G265= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs1332748311, COSV51154180; called by muse, mutect2, varscan2
- SLC30A8 | c.252C>T p.F84= | Silent (SNP) | VAF 63/122 reads (52%) | catalogued as rs756898981, COSV69968327; called by muse, mutect2, varscan2
- SLC35A5 | c.1059C>T p.F353= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV53728135; called by muse, mutect2, varscan2
- SLC35E1 | c.744C>T p.V248= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1413525491, COSV68736604; called by muse, mutect2, varscan2
- SLC44A2 | c.321C>G p.P107= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV59838027, COSV59839101; called by muse, mutect2
- SLF2 | c.3150G>A p.Q1050= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as COSV53280174; called by muse, mutect2, varscan2
- SMPD4 | c.1476C>T p.L492= (on ENST00000409031 / NM_017951.4; = p.L463= on NM_017751.4) | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1244565814, COSV60082979; called by muse, mutect2, varscan2
- SNX30 | c.705G>A p.L235= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV65294276; called by muse, mutect2, varscan2
- SPATA31D1 | c.1194C>G p.L398= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV61201541; called by muse, mutect2, varscan2
- SYNE2 | c.10521C>T p.L3507= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV59970837; called by muse, mutect2, varscan2
- SYT6 | c.1494G>A p.E498= (on ENST00000610222 / NM_001366225.1; = p.E413= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV65776273; called by muse, mutect2, varscan2
- TAF2 | c.9G>A p.L3= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV58088365; called by muse, mutect2, varscan2
- TAF6L | c.1356G>A p.L452= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1365499408, COSV53671019; called by muse, varscan2
- TENT4A | c.1929C>T p.L643= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV50097690, COSV50101486; called by muse, mutect2, varscan2
- TG | c.684C>T p.F228= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs776674941, COSV55094456; called by muse, mutect2, varscan2
- THADA | c.103C>T p.L35= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV101264117; called by muse, mutect2
- THOC2 | c.51G>A p.E17= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV55543826; called by muse, mutect2, varscan2
- TNFSF13B | c.72G>A p.L24= | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as COSV65515994; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1956C>T p.T652= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1464838897, COSV64100800; called by muse, mutect2, varscan2
- TWIST1 | c.477C>T p.L159= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV54250100, COSV54251627, COSV99643177; called by muse, mutect2, varscan2
- USP15 | c.2115G>C p.T705= (on ENST00000280377 / NM_001351159.2; = p.T676= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV54799034; called by muse, mutect2, varscan2
- USP25 | c.2166G>A p.L722= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV53490593; called by muse, mutect2, varscan2
- VEZT | c.526C>T p.L176= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as COSV54145269; called by muse, mutect2, varscan2
- VWF | c.819G>A p.R273= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1006469048, COSV54634882; called by muse, mutect2, varscan2
- WDR7 | c.970C>T p.L324= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV54363436; called by muse, mutect2
- ZBTB3 | c.270G>A p.L90= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV67361860, COSV67361987; called by muse, mutect2, varscan2
- ZNF335 | c.1155G>A p.E385= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs775800271, COSV59820300; called by muse, mutect2, varscan2
- ZNF552 | c.153C>T p.S51= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV66971961; called by muse, mutect2, varscan2
- ZNF704 | c.333C>T p.L111= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1294037066, COSV100589739; called by muse, mutect2, varscan2
- AFDN | chr6:167825740 G>A | 5'Flank (SNP) | VAF 16/72 reads (22%) | catalogued as rs1400666794; called by muse, mutect2, varscan2
- CALCA | chr11:14967767 C>T | 3'Flank (SNP) | VAF 14/60 reads (23%) | catalogued as COSV59028752; called by muse, mutect2, varscan2
- DCHS2 | n.3588G>C | RNA (SNP) | VAF 82/155 reads (53%) | catalogued as COSV59738325, COSV59740020; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14860G>A | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as rs868475732, COSV100229136; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14976G>A | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100232736; called by muse, mutect2, varscan2
- EIF4A1 | c.996+56C>T | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51510487, COSV99549138; called by muse, mutect2, varscan2
- EML2 | c.21-193T>A | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as rs1450351295, COSV99840267; called by mutect2, varscan2
- EPDR1 | c.-52C>T | 5'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99554579; called by muse, mutect2
- LAMTOR5 | chr1:110407812 G>A | 5'Flank (SNP) | VAF 9/35 reads (26%) | catalogued as COSV56679640; called by muse, mutect2, varscan2
- LINC01600 | n.1038G>A | RNA (SNP) | VAF 8/50 reads (16%) | catalogued as rs1388462939; called by muse, mutect2, varscan2
- MIR124-3 | n.86C>T | RNA (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- MIR518D | n.35C>T | RNA (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- NRG2 | c.1189+387G>A | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56840793; called by muse, mutect2, varscan2
- PHB2 | c.711+145G>A | Intron (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99781230; called by muse, mutect2, varscan2
- RPL7A | c.496-112C>T | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100034775; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+367C>G | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as COSV101530531; called by muse, mutect2, varscan2
- STAG3L4 | n.525G>A | RNA (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- STX3 | c.-1G>A | 5'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as rs1438096580, COSV100276141; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1875G>A | Intron (SNP) | VAF 48/168 reads (29%) | catalogued as COSV60363931; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
